Gene-level copy-number profile of tumor specimen HCM-SANG-0307-C15-01B from HCMI case HCM-SANG-0307-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0307-C15-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b62c494f-9580-4799-8340-99626c527708.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0307-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/850a7440-797b-4875-8b64-d5ddcaa06f8e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 637; copy number 1: 22,949; copy number 2: 34,301; copy number 3: 711; copy number 4: 28; copy number 5: 35; copy number 6: 109; copy number 7: 34; copy number 8: 25; copy number 10: 34; copy number 16: 32; copy number 46: 17.

Homozygous deletions (total copy number 0; autosomes only): 126 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:82,340,771–82,340,876, 1 gene (within-gene range 0–1): RNU6-441P.
- chr10:87,863,625–88,049,823, 5 genes (within-gene range 0–1): PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.
- chr14:68,236,243–68,422,196, 3 genes (within-gene range 0–1): RN7SL108P, AL122013.1, PPIAP6.
- chr15:20,073,699–22,437,902, 116 genes (broad region; genes not listed).
- chr21:34,668,994–34,718,227, 1 gene: CLIC6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 286 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–89,600,680, 3 genes, copy number 5: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr8:10,054,292–12,087,445, 68 genes, copy number 6–7 (broad region; genes not listed).
- chr8:12,333,644–12,418,090, 9 genes, copy number 7: RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P.
- chr8:12,628,476–15,238,431, 35 genes, copy number 6 (within-gene range 2–11): RPS3AP35, AC068587.3, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1.
- chr10:22,534,854–22,714,578, 2 genes, copy number 7: PIP4K2A, AL390318.1.
- chr10:25,174,802–25,602,229, 1 gene, copy number 5 (within-gene range 3–6): GPR158.
- chr10:25,393,557–25,819,426, 6 genes, copy number 5 (within-gene range 5–6): RN7SKP220, GPN3P1, LINC00836, HIRAP1, RNA5SP306, RNU6-632P.
- chr12:24,223,233–27,824,382, 83 genes, copy number 10–46 (within-gene range 1–46) (broad region; genes not listed).
- chr17:52,862,121–52,987,652, 2 genes, copy number 6: LINC02089, LINC02876.
- chr17:58,755,854–58,985,179, 1 gene, copy number 6 (within-gene range 1–6): PPM1E.
- chr17:58,835,899–60,666,280, 72 genes, copy number 5–8 (broad region; genes not listed).
- chr17:60,810,165–60,811,462, 1 gene, copy number 5 (within-gene range 3–5): KRT18P61.
- chr17:64,506,865–64,662,307, 3 genes, copy number 6 (within-gene range 1–6): CEP95, SMURF2, AC009994.1.

Autosomal genes at a single copy (total copy number 1): 20,606. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
